Somatic mutation profile of tumor specimen TCGA-VR-A8EO-01A (aliquot TCGA-VR-A8EO-01A-11D-A36J-09) from TCGA case TCGA-VR-A8EO, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 49.6 years (18,123 days).
Specimen TCGA-VR-A8EO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0a3e6b7-5ee5-4cb0-b2b1-e909470c4a48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VR-A8EO-10A (Blood Derived Normal), aliquot TCGA-VR-A8EO-10A-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f102e01d-7384-4d97-8c2c-002e6f992c17

The open-access MAF lists 52 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, Splice Site 2, Frame Shift Del 2, Intron 1, In Frame Del 1, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLA2G6 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs587784332, CM063029, COSV59267711; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 8/22 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC2 | c.650C>G p.S217W | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs565260681, COSV52018522, COSV52019339; called by muse, mutect2
- CLCA4 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201791111, COSV55368265; called by muse, mutect2, varscan2
- DCAF15 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1211267592; called by muse, mutect2, varscan2
- DEFB125 | c.148A>G p.R50G | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.382); catalogued as rs769435585; called by muse, mutect2, varscan2
- DNAAF1 | c.125-1G>T p.X42_splice | Splice Site (SNP) | VAF 10/19 reads (53%) | catalogued as COSV54741619; called by muse, mutect2, varscan2
- DNAH8 | c.12511C>T p.P4171S | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV100545806; called by muse, mutect2, varscan2
- IGHMBP2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 91/698 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as COSV99662157; called by muse, mutect2, varscan2
- LAMA5 | c.2074C>T p.R692W | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs777979653; called by muse, mutect2, varscan2
- LRP2 | c.13880C>T p.S4627L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs191145030, COSV99790773; called by muse, mutect2, varscan2
- MRPS12 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs150096976, COSV55500462; called by muse, mutect2, varscan2
- PDLIM3 | c.176C>T p.S59L (on ENST00000284770 / NM_001257963.1; = p.S226L on NM_014476.6) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs747243505, COSV99507586; called by muse, mutect2, varscan2
- SIGLEC5 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); catalogued as rs1360404047; called by muse, mutect2, varscan2
- SLC25A18 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 15/30 reads (50%) | catalogued as COSV100541042; called by muse, mutect2, varscan2
- TP53 | c.823del p.C275Vfs*70 | Frame Shift Del (DEL) | VAF 7/18 reads (39%) | catalogued as COSV52700773, COSV52771673; called by mutect2, pindel, varscan2
- VPS13B | c.4743G>C p.L1581F | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.796); catalogued as COSV100662218; called by muse, mutect2, varscan2
- WFDC8 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs750785099; called by muse, mutect2, varscan2
- ZNF562 | c.16A>G p.M6V | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs372227919; called by muse, mutect2, varscan2
- ABCD2 | c.1793-1G>A p.X598_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- ABCF3 | c.1592A>G p.K531R | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANGEL2 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CHUK | c.1317_1319del p.E439del | In Frame Del (DEL) | VAF 24/76 reads (32%) | called by pindel, varscan2
- GGT7 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GMEB2 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- HECTD4 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGKV1D-8 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MAPK6 | c.1823A>T p.N608I | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MROH1 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- PANK2 | c.1186A>T p.I396F (on ENST00000316562 / NM_153638.3; = p.I105F on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SEC24B | c.1673A>T p.D558V | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SLC25A3 | c.86_90del p.L29Qfs*26 (on ENST00000228318 / NM_005888.3; = p.L29Qfs*27 on NM_002635.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- SLCO1B3 | c.1933T>G p.F645V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPANXC | c.294G>T p.*98Yext*11 | Nonstop Mutation (SNP) | VAF 12/18 reads (67%) | called by mutect2, varscan2
- TBC1D32 | c.2539A>G p.N847D | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTK | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZGRF1 | c.5952T>A p.D1984E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZKSCAN3 | c.989G>C p.S330T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF415 | c.1577G>A p.C526Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKLE1 | c.1791C>T p.V597= (on ENST00000394458; = p.V543= on NM_152363.6) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs370950297; called by muse, mutect2, varscan2
- ANO9 | c.399G>A p.S133= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs552399217; called by muse, mutect2, varscan2
- COMT | c.468T>C p.A156= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- DCLK1 | c.990G>A p.S330= | Silent (SNP) | VAF 27/34 reads (79%) | catalogued as rs200783749, COSV55171920; called by muse, mutect2, varscan2
- H1-1 | c.84T>A p.A28= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs774107659; called by muse, mutect2, varscan2
- HGS | c.1335C>T p.S445= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV61270527; called by muse, mutect2, varscan2
- IKBKE | c.1392C>T p.S464= | Silent (SNP) | VAF 48/65 reads (74%) | catalogued as rs1553386791; called by muse, mutect2, varscan2
- MLXIPL | c.2487G>A p.L829= | Silent (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- PAX6 | c.420C>T p.D140= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1800427; called by muse, mutect2, varscan2
- SLC16A11 | c.1377C>T p.S459= (on ENST00000308009; = p.S435= on NM_153357.3) | Silent (SNP) | VAF 14/20 reads (70%) | called by muse, mutect2, varscan2
- TANC1 | c.1221C>T p.N407= | Silent (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- TTC39B | c.522C>A p.T174= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- FAIM | c.-23+1862C>T | Intron (SNP) | VAF 18/46 reads (39%) | catalogued as rs1325362583, COSV58158252; called by muse, mutect2
